Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9OF, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9OF-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

Prostate and seminal vesicles, radical prostatectomy: Prostatic adenocarcinoma, Gleason grade 3+3= 6, bilateral involvement, present at right apical margin; see comment.

COMMENT:

Select slides (slide A7) were shown at the

the

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** right and left apex (A1, A2); right anterior apex, mid, base (A3-A6); right posterior apex, base (A7, A9); left posterior apex, mid (A10,A11); left anterior apex, mid, base (A13-A16).
- **Estimated volume of tumor:** 2.4 cm3.
- **Gleason score:** 3+3.
- **Estimated volume > Gleason pattern 3:** 0.
- **Involvement of capsule:** Tumor invades capsule (slides A3,A7,A10).
- **Extraprostatic extension:** None.
- **Margin status for tumor:** Positive (right apex, slides A1 and A3).
- **Margin status for benign glands:** Benign glands present at inked extension margins.
- **Involvement of seminal vesicle:** None.
- **Perineural infiltration:** None.
- **Prostatic intraepithelial neoplasia (PIN):** None.
- **Lymph node status:** None present.
- **AJCC/UICC stage:** pT2cNXMX.

Specimen(s) Received

A: Prostate and bilateral seminal vesicles

Clinical History

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
QID 8/22/14

[page 2 of 2]
The patient is a [REDACTED] with history of prostate cancer by core biopsy, Gleason grade 3+3 = 6, clinical stage T1cNXM0. The patient undergoes robot-assisted radical prostatectomy.

Gross Description

The specimen is received fresh in one part labeled with the patient's name, unit number and "prostate and BSV." It consists of a single intact prostate gland with attached seminal vesicle/vas deferens bundles, which on cut section reveals a suspicious area of yellow-gold, lobulated tissue just anterior to the urethral channel in serial slices 1 and 2, as well as a solid, white-tan tumor nodule in the right lateral aspect of serial slices 3 and 4. The specimen weighs 37 grams and measures 3.5 cm from apex to base, 4 cm from medial to lateral and 3.5 cm from anterior to posterior. The external surface is relatively smooth, red-tan and glistening. The bladder margin demonstrates extensive cautery. The dorsal vein complex is closed with the use of a single suture. The seminal vesicle/vas deferens bundles are soft, red-tan and whorled, without obvious lesion or mass. The right anterior resection margin is inked green. The left anterior resection margin is inked blue. The posterior resection margin is inked black. An incision is made in the posterior surface between apex and midgland, with tissue being banked for research purposes. The incision is glued shut, and the specimen is fixed prior to further sectioning. Following fixation, the bladder margin is removed, and the remainder of the gland is serially sectioned from apex to base perpendicular to the urethral channel into eight serial slices. The slices reveal a 1.1 cm foci of bright yellow-gold, slightly lobulated tissue just anterior to the urethral channel in serial slices 1 and 2. Additionally, there is a solid, white-tan, 1.2-cm lesion in the right lateral aspect of serial slices 3 and 4. This lesion grossly abuts the lateral to posterior inked surgical margin. The central-transition zone is of normal size and appearance and composed of firm, white-tan, striated and nodular tissue. The peripheral zone, making up approximately two-thirds of total gland volume, is composed of softer, semiporous, light tan tissue where unaffected by tumor. The apical and bladder margin, as well as representative sections of the prostate and seminal vesicles, are submitted as follows:

Apical Margin (Serial Slice 1)

Cassette A1: Right apex.

Cassette A2: Left apex.

Right Anterior Quadrant

Cassette A3: Serial slice 2.

Cassette A4: Serial slice 3.

Cassette A5: Serial slice 5.

Cassette A6: Serial slice 7.

Right Posterior Quadrant

Cassette A7: Serial slice 3.

Cassette A8: Serial slice 5.

Cassette A9: Serial slice 7.

Left Posterior Quadrant

Cassette A10: Serial slice 3.

Cassette A11: Serial slice 5.

Cassette A12: Serial slice 7.

Left Anterior Quadrant

Cassette A13: Serial slice 2.

Cassette A14: Serial slice 3.

Cassette A15: Serial slice 5.

Cassette A16: Serial slice 7.

Bladder Margin

Cassette A17: Right bladder margin.

Cassette A18: Left bladder margin.

Prostatic/Seminal Vesicle Junction

Cassette A19: Right seminal vesicle and cross section of vas deferens.

Cassette A20: Left seminal vesicle and cross section of vas deferens.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed

Source: NCI Genomic Data Commons file 537b59fc-f828-44c8-8181-d4e0a095d246 (TCGA-V1-A9OF.1C729709-EE1B-421E-A55A-7A048806FA6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).